CPTAC case C3N-00180 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6d268ea7-eea0-4984-9e78-1b959f7e9a2a

Demographics
Sex at birth: male; Race: asian; Year of birth: 1960; Vital status: Dead; Days to death: 355 days; Year of death: 2017; Country of birth: Vietnam.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 56.5 years (20,625 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Residual disease: R0; Days to last known disease status: 355 days; Progression or recurrence: no; Days to last follow up: 355 days; Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 4.5 cm (a second GDC size field records 3.5 cm); Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 7; Margin status: Uninvolved.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 355.

Other clinical attributes
- Weight: 50 kg; Height: 170 cm; BMI: 17.3.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 7.5; Cigarettes per day: 5; Tobacco smoking onset year: 1986; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 36.

Biospecimens (7 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Samples C3N-00180-01, C3N-00180-03, C3N-00180-04 (3 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 250 mg.
- Sample C3N-00180-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 8 days; Initial weight: 250 mg; Time between clamping and freezing: 24 minutes; Time between excision and freezing: 2 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00180-22: Section location: Left lung, hilar area; Percent tumor nuclei: 80; Percent necrosis: 20.
- Sample C3N-00180-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 8 days; Initial weight: 200 mg; Time between clamping and freezing: 26 minutes; Time between excision and freezing: 4 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-00180-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 200 mg.
- Sample C3N-00180-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 8 days; Method of sample procurement: Blood Draw.
